Surgical pathology report (de-identified scan), TCGA case TCGA-06-0745, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0745-01A (Primary Tumor).

[page 1 of 2]
TCGA-06-0745

Surgical Pathology Report

CLINICAL HISTORY
Not Given

OPERATIVE DIAGNOSES
Not Given

Operation/Specimen: A: Brain, tumor, biopsy
B: Brain, tumor, biopsy

PATHOLOGICAL DIAGNOSIS:
A and B. Brain biopsy: Glioblastoma multiforme, proliferation index (MIB-1) : 40%

COMMENT
This is a high grade glioma with increased mitotic figure, prominent vascular hyperplasia and areas of necrosis, .

PROCEDURES/ADDENDA

MGMT Promoter Methylation
Date Ordered: [REDACTED]

Date Reported: [REDACTED]

Interpretation

NEGATIVE - No evidence of methylated MGMT promoter is detected.

Results-Comments

Received were paraffin curls labeled

TEST DESCRIPTION: Bisulfite treatment of DNA followed by PCR amplification of both methylated and unmethylated MGMT promoter sequences, with products detected by gel electrophoresis.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

[page 2 of 2]
[REDACTED]

determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

=====

INTRA-OPERATIVE CONSULTATION

A. Brain, biopsy: Glioma, 1 block, [REDACTED]

[REDACTED]

GROSS DESCRIPTION

A. Multiple tissue fragments, 0.3 to 0.6 cm, All in A1, A2
B. One 0.5 cm tissue fragment, all in B1

[REDACTED]

ICD-9(s):
191.2 191.2

[REDACTED]

Histo Data

Part A: Brain,tumor, biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1	[REDACTED]	
H/E x 1	2	[REDACTED]	
MGMT x 1	2	[REDACTED]	
MIB1-DA x 1	2	[REDACTED]	

Part B: Brain,tumor, biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1	[REDACTED]	

*** End of Report ***

Source: NCI Genomic Data Commons file 3eb31888-4409-4a46-8bd7-2d52f1c8f6cc (TCGA-06-0745.F46F4B25-6E54-4C40-842A-1C5C6DD99CAB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).